Surgical pathology report (de-identified scan), TCGA case TCGA-CM-6678, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-6678-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

[REDACTED]

[REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

....

Clinical Diagnosis & History:
History of synchronous stage IV colon cancer.

Specimens Submitted:
1: Left colon, colectomy
2: Gallbladder
3: Hepatic artery lymph node

DIAGNOSIS:
1. Left colon, colectomy:
Tumor Type:
Adenocarcinoma
Histologic Grade:
Moderately differentiated
Tumor Location:
Sigmoid colon
Tumor Size:
5 x 2 x 0.4 cm
Tumor Budding:
Focal
Increased Tumor Infiltrating Lymphocytes:
Absent
Precursor Lesions:
Not identified
Deepest Tumor Invasion:
Serosal surface
Gross Tumor Perforation:
Not identified
Lymphovascular Invasion:
Not identified
Large Venous Invasion:
Not Identified
Perineural Invasion:
Not identified
Surgical Margins:
Free of tumor
Polyps/Mucosa Dysplasia (away from the carcinoma):
Not Identified
Non-Neoplastic Bowel:
Unremarkable

** Continued on next page **

[page 2 of 4]
Lymph Nodes:

Number with metastasis: 0

Total number examined: 19

Tumor deposits in pericorectal soft tissue:

Identified

Identified; number:1

Tumor Staging (AJCC 7th Edition):

pT4a (Tumor penetrates to the surface of the visceral peritoneum)

Lymph Node Stage (AJCC 7th Edition):

N1c (Tumor deposit(s) in the subserosa, mesentery, or nonperitonealized pericolic or perirectal tissues without regional nodal metastasis)

2. Gallbladder; cholecystectomy:

- Mild chronic cholecystitis and cholelithiasis.

3. Hepatic artery lymph node; excision:

- One benign lymph node (0/1).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	EVG	

Gross Description:

1).The specimen is received fresh and is labeled "left colon, stitch marks proximal". It consists of a sigmoid colon that measures 20 CM in length and five CM in diameter. The serosal surface is focally puckered and wrapped by fat towards the distal aspect of the specimen. The radial serosal surface is inked black and the specimen is opened to reveal an ulcerated tumor measuring 5x2x0.4 cm causing slight constriction near the proximal end. Tumor is located 13 cm from the distal margin and 6 cm from the proximal margin. Serial sectioning reveals tumor invasion to a depth of 0.4 cm penetrating through the muscularis propria.. The remaining mucosa appears grossly unremarkable. Pericolic and peri-rectal adipose tissue is thoroughly examined for lymph nodes, and all possible nodes are submitted. Representative sections are submitted. TPS is submitted.

Summary of sections:

PM - proximal margin

DM - distal margin

T - Tumor

** Continued on next page **

[page 3 of 4]
U - Uninvolved mucosa
LN - lymph nodes

2) The specimen is received in formalin, labeled "Gallbladder" and consists of a variegated pink-tan to red purple gallbladder measuring 7.0 x 3.5 x 3.0 cm. The surface of the gallbladder is smooth and glistening with no apparent defects. It is opened to reveal 30 cc of green black bile, with a yellow black multi-lobulated friable gallstone attached to the mucosal surface. The remainder of the mucosa is yellow-green smooth and velvety. The wall thickness measures up to 0.2 cm. Representative sections including the cystic duct margin are submitted.

Summary of sections:
M - cystic duct margin
U - undesignated

3) The specimen is received in formalin, labeled "hepatic artery lymph node" and consists of a pink-tan rubbery lymph node measuring 1.3 x 1.0 x 0.5 cm. The lymph node is bisected and entirely submitted.

Summary of sections:
BLN - lymph node

Summary of Sections:
Part 1: Left colon, colectomy

Block	Sect.	Site	PCs
1		dm	1
6		ln	16
1		pm	1
6		t	6
1		u	1

Part 2: Gallbladder

Block	Sect.	Site	PCs
1		M	1
1		U	4

Part 3: Hepatic artery lymph node

Block	Sect.	Site	PCs
-------	-------	------	-----

** Continued on next page **

[page 4 of 4]
[REDACTED]

** End of Report **

Source: NCI Genomic Data Commons file 648e2ac6-f4c2-452e-99c4-7288d4ebe248 (TCGA-CM-6678.B9528D91-A511-4057-BE4B-86C1496778FF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).